Somatic mutation profile of tumor specimen C3N-03018-02 (aliquot CPT0188980011) from CPTAC case C3N-03018, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.6 years (23,958 days).
Specimen C3N-03018-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8744d9e-7c33-4ff5-acf0-268c1541a8f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03018-31 (Blood Derived Normal), aliquot CPT0189020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5b9b913-0b34-4716-b09d-a86a2a8d165f

The open-access MAF lists 101 somatic variants for this specimen: 75 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 16, Frame Shift Del 6, Splice Site 4, 3'UTR 4, Intron 2, RNA 2, Nonsense Mutation 1, 5'Flank 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1918G>C p.V640L (on ENST00000288602 / NM_001374244.1; = p.V600L on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VHL | c.240T>A p.S80R | Missense Mutation (SNP) | VAF 219/430 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as CM941367, COSV56542846, COSV56543658; called by muse, mutect2, varscan2
- ALPP | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1559237986; called by mutect2, varscan2
- ANKRD33B | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1275025696, COSV56976991; called by muse, mutect2, varscan2
- COL11A1 | c.3385-2A>T p.X1129_splice | Splice Site (SNP) | VAF 78/339 reads (23%) | catalogued as CS993223; called by muse, mutect2, varscan2
- CUL3 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52362135, COSV99049305; called by muse, mutect2, varscan2
- DDX3X | c.299G>A p.R100Q (on ENST00000399959; = p.R101Q on NM_001356.5) | Missense Mutation (SNP) | VAF 95/137 reads (69%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as rs1311783625; called by muse, mutect2, varscan2
- DLG4 | c.2117G>T p.R706L (on ENST00000399506 / NM_001321075.3; = p.R749L on NM_001365.4) | Missense Mutation (SNP) | VAF 138/364 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV57239791; called by muse, mutect2, varscan2
- DOCK3 | c.2941T>A p.F981I | Missense Mutation (SNP) | VAF 90/192 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV104382324; called by muse, mutect2, varscan2
- EBF2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754762615, COSV68777377; called by muse, mutect2, varscan2
- IFT74 | c.1237A>G p.I413V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs955805697; called by muse, mutect2, varscan2
- KRT24 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs757855838; called by muse, mutect2, varscan2
- LRP2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 33/490 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs774803256, COSV99788697; called by muse, mutect2
- MED8 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51940977; called by muse, mutect2, varscan2
- MRM2 | c.8+1G>A p.X3_splice | Splice Site (SNP) | VAF 135/330 reads (41%) | catalogued as COSV54248658; called by muse, mutect2, varscan2
- NUDCD1 | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763172759; called by muse, mutect2, varscan2
- PCDHGA1 | c.2228T>C p.V743A | Missense Mutation (SNP) | VAF 48/1119 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs1277383210, COSV65297263; called by muse, mutect2
- PLTP | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 275/816 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.83); catalogued as COSV99509793; called by muse, mutect2, varscan2
- QRFPR | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751553958, COSV57677217; called by muse, mutect2, varscan2
- RYR3 | c.7226C>T p.A2409V (on ENST00000389232; = p.A2410V on NM_001036.6) | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs769067753; ClinVar: uncertain significance; called by mutect2, varscan2
- SOX18 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs976296449; called by muse, mutect2, varscan2
- VEGFA | c.367C>A p.L123I (on ENST00000523873 / NM_001171623.1; = p.L303I on NM_003376.6) | Missense Mutation (SNP) | VAF 69/513 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.853); catalogued as COSV100035632; called by muse, mutect2, varscan2
- AC008397.2 | c.69C>G p.H23Q | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2
- ADGRA1 | c.1507del p.E503Rfs*34 | Frame Shift Del (DEL) | VAF 50/244 reads (20%) | called by mutect2, pindel, varscan2
- AGO2 | c.2433C>A p.F811L | Missense Mutation (SNP) | VAF 32/599 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2
- BAZ2B | c.6154_6155insA p.F2052Yfs*5 | Frame Shift Ins (INS) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- BRD9 | c.753_764del p.E252_V255del | In Frame Del (DEL) | VAF 54/201 reads (27%) | called by mutect2, pindel, varscan2
- CDH18 | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 101/502 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- CLEC16A | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- COL4A4 | c.4492G>A p.G1498R | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTC1 | c.1717C>G p.L573V | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- EPHA8 | c.2377T>A p.Y793N | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- FAM111A | c.228G>T p.R76S | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAM32A | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.364); called by muse, mutect2
- FBXO11 | c.1742G>C p.C581S (on ENST00000403359 / NM_001190274.2; = p.C497S on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- FRYL | c.2127_2130del p.L710Efs*19 | Frame Shift Del (DEL) | VAF 64/163 reads (39%) | called by mutect2, pindel, varscan2
- FSIP2 | c.20416T>G p.S6806A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- GALNT1 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- GATD1 | c.392T>A p.L131Q | Missense Mutation (SNP) | VAF 121/434 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- GNE | c.1385T>C p.V462A (on ENST00000396594 / NM_001128227.3; = p.V431A on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- HERPUD1 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- HNRNPUL2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- HYKK | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IPO5 | c.1983C>G p.N661K | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KDM5C | c.2368+2_2368+3del p.X790_splice | Splice Site (DEL) | VAF 170/300 reads (57%) | called by mutect2, pindel, varscan2
- KIAA2026 | c.3671G>T p.S1224I | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEL2 | c.775A>T p.M259L | Missense Mutation (SNP) | VAF 101/290 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- MEIS2 | c.320G>C p.G107A (on ENST00000561208 / NM_170675.5; = p.G94A on NM_002399.3) | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MMP21 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MTHFD1 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 262/537 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO9B | c.4948C>A p.L1650I | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NINL | c.3847del p.E1283Nfs*6 | Frame Shift Del (DEL) | VAF 79/262 reads (30%) | called by mutect2, pindel, varscan2
- NOD2 | c.1741del p.S581Lfs*182 | Frame Shift Del (DEL) | VAF 94/317 reads (30%) | called by mutect2, pindel, varscan2
- PDZK1 | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 62/158 reads (39%) | called by muse, mutect2, varscan2
- PER2 | c.774T>C p.D258= | Splice Region (SNP) | VAF 66/133 reads (50%) | called by muse, mutect2, varscan2
- PEX5 | c.120G>C p.W40C | Missense Mutation (SNP) | VAF 104/538 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, varscan2
- PPIE | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTGS1 | c.1373G>C p.R458P | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPUSD4 | c.961C>G p.H321D | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SECISBP2 | c.2462T>G p.I821S | Missense Mutation (SNP) | VAF 127/312 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- SGO2 | c.1316T>A p.L439Q | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SLC17A5 | c.1112-1G>A p.X371_splice | Splice Site (SNP) | VAF 134/359 reads (37%) | called by muse, mutect2, varscan2
- SLC4A10 | c.1978G>A p.E660K (on ENST00000446997 / NM_001354461.2; = p.E630K on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SOX1 | c.800G>C p.S267T | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, varscan2
- ST18 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0); called by mutect2, varscan2
- TAOK2 | c.2498G>A p.S833N | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC6A | c.2451del p.Q818Sfs*85 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | called by mutect2, pindel, varscan2
- TSGA10IP | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2
- UBE2R2 | c.137del p.F46Sfs*33 | Frame Shift Del (DEL) | VAF 158/463 reads (34%) | called by mutect2, pindel, varscan2
- UBN2 | c.2408A>G p.E803G | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UGT3A1 | c.1448A>T p.Q483L | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- YARS2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ZFYVE26 | c.3466T>A p.F1156I | Missense Mutation (SNP) | VAF 198/378 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ZNF737 | c.985A>T p.T329S | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZSCAN25 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 149/578 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ATP7A | c.3849T>A p.V1283= | Silent (SNP) | VAF 112/160 reads (70%) | called by muse, mutect2, varscan2
- CLDN16 | c.417T>C p.A139= | Silent (SNP) | VAF 274/389 reads (70%) | called by muse, mutect2, varscan2
- DOP1A | c.519T>A p.A173= | Silent (SNP) | VAF 46/127 reads (36%) | called by muse, mutect2, varscan2
- FLT1 | c.3265C>T p.L1089= | Silent (SNP) | VAF 113/392 reads (29%) | catalogued as rs775806397, COSV56744563; called by muse, mutect2, varscan2
- GRIP1 | c.1431A>T p.A477= (on ENST00000359742 / NM_001379345.1; = p.A425= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 82/195 reads (42%) | called by muse, mutect2, varscan2
- KCNH5 | c.1887C>T p.N629= | Silent (SNP) | VAF 89/184 reads (48%) | catalogued as rs373387419; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEGF8 | c.1329G>A p.Q443= | Silent (SNP) | VAF 73/176 reads (41%) | called by muse, mutect2, varscan2
- MPHOSPH8 | c.267C>T p.T89= | Silent (SNP) | VAF 73/191 reads (38%) | catalogued as rs1195879472, COSV64055639; called by muse, mutect2, varscan2
- NKAIN4 | c.598T>C p.L200= | Silent (SNP) | VAF 77/236 reads (33%) | called by muse, mutect2, varscan2
- PMF1 | c.276C>T p.I92= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as COSV60771607; called by muse, mutect2, varscan2
- PSMD4 | c.909G>T p.A303= | Silent (SNP) | VAF 39/479 reads (8%) | catalogued as COSV100924650; called by muse, mutect2
- RGS7 | c.66G>A p.L22= | Silent (SNP) | VAF 20/478 reads (4%) | called by muse, mutect2
- SLC4A9 | c.639G>A p.Q213= (on ENST00000507527 / NM_001258428.2; = p.Q189= on NM_031467.3) | Silent (SNP) | VAF 91/270 reads (34%) | called by muse, mutect2, varscan2
- SPAM1 | c.390C>T p.D130= | Silent (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- TAF4B | c.1443T>G p.L481= | Silent (SNP) | VAF 103/197 reads (52%) | called by muse, mutect2, varscan2
- TMEM67 | c.2373T>C p.G791= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- AKAP7 | c.*806G>C | 3'UTR (SNP) | VAF 46/153 reads (30%) | called by muse, mutect2, varscan2
- C10orf105 | c.-32C>T | 5'UTR (SNP) | VAF 237/576 reads (41%) | called by muse, mutect2, varscan2
- CHST10 | c.-104+339A>G | Intron (SNP) | VAF 19/367 reads (5%) | called by muse, mutect2
- GANAB | c.*438A>C | 3'UTR (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2
- MST1R | c.3065-13C>A | Intron (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- TAZ | c.*557C>T | 3'UTR (SNP) | VAF 267/382 reads (70%) | called by muse, mutect2, varscan2
- TBC1D3P2 | n.271C>T | RNA (SNP) | VAF 32/186 reads (17%) | catalogued as rs201416701; called by mutect2, varscan2
- TMEM37 | chr2:119429913 G>A | 5'Flank (SNP) | VAF 58/171 reads (34%) | called by muse, mutect2, varscan2
- TTC41P | n.2955A>T | RNA (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- UBE2B | c.*30C>T | 3'UTR (SNP) | VAF 81/274 reads (30%) | called by muse, mutect2, varscan2
